Somatic mutation profile of tumor specimen TCGA-BB-4228-01A (aliquot TCGA-BB-4228-01A-01D-1434-08) from TCGA case TCGA-BB-4228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 50.7 years (18,536 days).
Specimen TCGA-BB-4228-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8542b6f-921f-4724-8be0-be03578442c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4228-10A (Blood Derived Normal), aliquot TCGA-BB-4228-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4682f05d-e3a3-4ec0-970a-9ef9b67cd349

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 4, In Frame Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 39/121 reads (32%) | catalogued as rs1393544920, COSV100483393, COSV58591239; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 108/239 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAL | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV101052483; called by muse, mutect2, varscan2
- ADAM2 | c.1318T>A p.S440T | Missense Mutation (SNP) | VAF 352/474 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV99696662; called by muse, mutect2, varscan2
- AP2A2 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs760009895, COSV59963856; called by muse, mutect2, varscan2
- ARMC3 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV53068157, COSV99957399; called by muse, mutect2, varscan2
- CATSPER1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs543744984, COSV56408716; called by muse, mutect2, varscan2
- CCDC40 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1229219183, COSV53904511; called by muse, mutect2, varscan2
- CRCT1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | PolyPhen benign (0.271); catalogued as COSV100524153; called by muse, mutect2, varscan2
- DAGLA | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs777615529, COSV57198008, COSV99078705; called by muse, mutect2, varscan2
- EFCAB5 | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562656184, COSV57933675; called by muse, mutect2, varscan2
- FNDC1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1384956388, COSV51933311; called by muse, varscan2
- FZD3 | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99527832; called by muse, mutect2, varscan2
- GNB2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV51948787; called by muse, mutect2, varscan2
- HMGCR | c.1740C>A p.S580R | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99843001; called by muse, mutect2, varscan2
- IFRD2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs782437208, COSV100269249; called by muse, mutect2, varscan2
- ITGAL | c.2714C>G p.S905* | Nonsense Mutation (SNP) | VAF 60/143 reads (42%) | catalogued as COSV100776049; called by muse, mutect2, varscan2
- KCNT2 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs781172493, COSV54063065; called by muse, mutect2, varscan2
- KRTAP10-7 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV100169980; called by muse, varscan2
- MRPL3 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394573; called by muse, mutect2
- PCDHA3 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100973546; called by muse, mutect2, varscan2
- PKNOX2 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as rs750944288, COSV100019950; called by muse, mutect2, varscan2
- PLG | c.1628G>A p.C543Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804210; called by muse, mutect2, varscan2
- RIPK4 | c.2146T>C p.S716P (on ENST00000352483; = p.S668P on NM_020639.3) | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.295); catalogued as COSV100204619; called by muse, mutect2, varscan2
- STK35 | c.1577G>A p.R526K | Missense Mutation (SNP) | VAF 70/80 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV99852577, COSV99852960; called by muse, mutect2, varscan2
- SYNCRIP | c.1799A>T p.H600L | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.045); catalogued as rs147197492; called by muse, mutect2, varscan2
- TRAF3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 29/37 reads (78%) | catalogued as COSV61026797; called by muse, mutect2, varscan2
- ZIM2 | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV99687106; called by muse, mutect2, varscan2
- IRF2BP2 | c.1299_1301del p.N434del | In Frame Del (DEL) | VAF 103/265 reads (39%) | called by mutect2, pindel, varscan2
- KPRP | c.454_456del p.N152del | In Frame Del (DEL) | VAF 82/212 reads (39%) | called by mutect2, pindel, varscan2
- ACER1 | c.426C>T p.N142= | Silent (SNP) | VAF 84/197 reads (43%) | catalogued as rs368558992, COSV56835276; called by muse, mutect2, varscan2
- CSMD1 | c.2706G>A p.P902= (on ENST00000520002; = p.P901= on NM_033225.6) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs374751635, COSV59294283; called by muse, mutect2, varscan2
- DMWD | c.843G>A p.A281= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs375340062, COSV99353750; called by muse, mutect2, varscan2
- FAT4 | c.10800A>G p.G3600= | Silent (SNP) | VAF 133/293 reads (45%) | catalogued as COSV100627186; called by muse, mutect2, varscan2
- ITGAL | c.2847C>T p.V949= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as COSV100776050; called by muse, mutect2, varscan2
- PIM1 | c.666G>A p.S222= | Silent (SNP) | VAF 79/198 reads (40%) | catalogued as rs993864858, COSV100998593; called by muse, mutect2, varscan2
- SOGA3 | c.2265C>T p.S755= | Silent (SNP) | VAF 112/250 reads (45%) | catalogued as COSV64105394; called by muse, varscan2
- TLE5 | c.357G>A p.L119= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1441948189, COSV99682229; called by muse, mutect2, varscan2
- TSR1 | c.1903+165G>C | Intron (SNP) | VAF 52/112 reads (46%) | catalogued as COSV100026836; called by muse, mutect2, varscan2
